Somatic mutation profile of tumor specimen TCGA-FS-A1ZZ-06A (aliquot TCGA-FS-A1ZZ-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.8 years (20,396 days).
Specimen TCGA-FS-A1ZZ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a08515c7-c522-42ae-9be2-7a760abba8e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZZ-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZZ-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14ac1066-7eeb-49ad-bbef-006c8976e5af

The open-access MAF lists 1,842 somatic variants for this specimen: 1,152 protein-altering or splice-affecting, 641 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,052, Silent 641, Nonsense Mutation 64, Intron 19, RNA 16, Splice Region 15, Splice Site 12, 5'Flank 7, 3'Flank 4, Nonstop Mutation 3, Frame Shift Del 3, 5'UTR 3.

Variants (750 of 1,842; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.6304C>T p.R2102C | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767019228, COSV54204048; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 46/49 reads (94%) | catalogued as rs727503777, CM150966, COSV63281970; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 50/53 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514553, CM128754, COSV54738538, COSV54759872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RP2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556318633, CM033008, CM077334, COSV54460861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52194249; called by muse, varscan2
- ABCA8 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs866649283, COSV52194270; called by muse, varscan2
- ABCB1 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55945144; called by muse, varscan2
- ABCB5 | c.1885G>A p.D629N (on ENST00000404938 / NM_001163941.2; = p.D184N on NM_178559.6) | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.76); catalogued as COSV51703027; called by muse, mutect2, varscan2
- ABCD3 | c.1980G>C p.*660Yext*18 | Nonstop Mutation (SNP) | VAF 90/95 reads (95%) | catalogued as COSV64642367; called by muse, mutect2, varscan2
- ABHD1 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53204465; called by muse, mutect2, varscan2
- ABLIM2 | c.1555G>A p.G519R (on ENST00000341937 / NM_001130084.2; = p.G553R on NM_001130083.2) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.162); catalogued as COSV56400089; called by muse, mutect2, varscan2
- AC007040.2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868932884, COSV55536372; called by muse, mutect2, varscan2
- ACBD5 | c.1051C>T p.R351C (on ENST00000375888 / NM_001352568.1; = p.R342C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755306488, COSV65517960; called by muse, mutect2, varscan2
- ACE | c.3515A>G p.K1172R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); catalogued as COSV52003347; called by muse, mutect2, varscan2
- ACO1 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV59376761; called by muse, mutect2, varscan2
- ACSL5 | c.1240C>T p.R414C (on ENST00000354273; = p.R470C on NM_016234.3) | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs767315343, COSV100634493, COSV61128829; called by muse, mutect2, varscan2
- ACSM4 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as rs752573137, COSV68066628; called by muse, mutect2, varscan2
- ACSM4 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV68066637; called by muse, mutect2, varscan2
- ACTL7A | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs867346152, COSV61776262; called by muse, mutect2, varscan2
- ADAD2 | c.1067C>T p.S356L (on ENST00000315906 / NM_001145400.2; = p.S438L on NM_139174.4) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs531531110, COSV51892372; called by muse, mutect2, varscan2
- ADAD2 | c.1537G>A p.G513R (on ENST00000315906 / NM_001145400.2; = p.G595R on NM_139174.4) | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV51892376, COSV51894872; called by muse, mutect2, varscan2
- ADAM18 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55843778; called by muse, mutect2, varscan2
- ADAM19 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.129); catalogued as COSV57422897; called by muse, varscan2
- ADAM22 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55969639; called by muse, mutect2, varscan2
- ADAM30 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 544/584 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs368258402; called by muse, mutect2, varscan2
- ADAM7 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV51535057; called by muse, mutect2, varscan2
- ADAMDEC1 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.464); catalogued as COSV56474062; called by muse, mutect2, varscan2
- ADAMTS14 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1031540008, COSV64599621; called by muse, mutect2, varscan2
- ADAMTS15 | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 84/95 reads (88%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs780638377, COSV54502904; called by muse, mutect2
- ADAMTS20 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67126064; called by muse, mutect2, varscan2
- ADCY1 | c.1631A>C p.E544A | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52030061; called by muse, mutect2, varscan2
- ADD2 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV52454870; called by muse, mutect2, varscan2
- ADGRF4 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV51949520; called by muse, mutect2, varscan2
- ADGRG2 | c.1399G>A p.A467T (on ENST00000379869 / NM_001079858.3; = p.A464T on NM_005756.4) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV61337516; called by muse, mutect2, varscan2
- ADGRV1 | c.14971C>G p.R4991G | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV67978496; called by muse, mutect2, varscan2
- ADH1B | c.914A>G p.N305S | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV59295059; called by muse, mutect2, varscan2
- ADH4 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.399); catalogued as COSV55500061; called by muse, mutect2, varscan2
- AFF2 | c.2718A>C p.R906S | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV53976660; called by muse, mutect2, varscan2
- AFF4 | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV54791464; called by muse, mutect2, varscan2
- AGPAT4 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755678797, COSV57242883; called by muse, mutect2, varscan2
- AHNAK | c.537A>T p.E179D | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as COSV57203595; called by muse, mutect2, varscan2
- AHNAK2 | c.6101C>T p.T2034I | Missense Mutation (SNP) | VAF 70/105 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs1157085523, COSV60907668; called by muse, mutect2, varscan2
- AK7 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs759825760, COSV50869227; called by muse, mutect2, varscan2
- AKR1C4 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54122293, COSV54122714; called by muse, mutect2, varscan2
- ALDH1A2 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51078132; called by muse, mutect2, varscan2
- ALDH1B1 | c.1284G>C p.K428N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV66619232; called by muse, mutect2, varscan2
- ALDH7A1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs181287032, COSV63160706; ClinVar: uncertain significance; called by muse, varscan2
- ALKBH8 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV52833314; called by muse, mutect2, varscan2
- ALOX12 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV52348515; called by muse, mutect2, varscan2
- ALPK1 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.539); catalogued as COSV51581869; called by muse, mutect2, varscan2
- AMER1 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV57654863; called by muse, mutect2, varscan2
- AMFR | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV99315747; called by muse, mutect2, varscan2
- ANGPTL1 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402538302, COSV52365362; called by muse, mutect2, varscan2
- ANK1 | c.2767G>A p.G923S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55872764, COSV55887544; called by muse, mutect2, varscan2
- ANK3 | c.9118G>A p.E3040K | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); catalogued as COSV55044241; called by muse, varscan2
- ANK3 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 34/61 reads (56%) | catalogued as COSV55044248; called by muse, varscan2
- ANK3 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55044257; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs774973824, COSV51840553; called by muse, mutect2, varscan2
- ANKRD30A | c.3328G>A p.E1110K (on ENST00000611781; = p.E1054K on NM_052997.2) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs267602485, COSV64603763; called by muse, mutect2, varscan2
- ANKRD34B | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.048); catalogued as rs377516382; called by muse, mutect2, varscan2
- ANKS1B | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV61335084, COSV61338267; called by muse, varscan2
- ANKS1B | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as rs745539676, COSV61335090; called by muse, varscan2
- ANO3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV56780653; called by muse, mutect2, varscan2
- ANO3 | c.2341T>G p.L781V | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.734); catalogued as rs11825056; called by muse, mutect2, varscan2
- ANO4 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54585481; called by muse, mutect2, varscan2
- ANO4 | c.169G>A p.D57N (on ENST00000392977 / NM_001286615.2; = p.D22N on NM_178826.4) | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.956); catalogued as rs373885901; called by muse, mutect2, varscan2
- ANO9 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV60448130, COSV60448376; called by muse, mutect2, varscan2
- ANXA4 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755577388, COSV67848315; called by muse, mutect2, varscan2
- AOAH | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51735702; called by muse, mutect2, varscan2
- APOA4 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 79/92 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV63360000; called by muse, mutect2, varscan2
- APOB | c.11182G>A p.D3728N | Missense Mutation (SNP) | VAF 283/616 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.149); catalogued as rs1198549888, COSV51923344; called by muse, mutect2, varscan2
- APOBEC3F | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1424009154, COSV100415147; called by muse, varscan2
- APOBEC3H | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62378484; called by muse, mutect2, varscan2
- AQR | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV50029589; called by muse, varscan2
- ARHGAP35 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 54/126 reads (43%) | catalogued as rs1324454897, COSV68329190; called by muse, varscan2
- ARHGAP4 | c.498G>A p.T166= | Splice Region (SNP) | VAF 10/12 reads (83%) | catalogued as COSV100603790, COSV63130724; called by muse, varscan2
- ARHGAP5 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.296); catalogued as COSV61533919; called by muse, mutect2, varscan2
- ARHGAP6 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV57290916; called by muse, mutect2
- ARID1B | c.6478C>T p.Q2160* | Nonsense Mutation (SNP) | VAF 24/29 reads (83%) | catalogued as rs1554238125, COSV51648834; called by muse, mutect2, varscan2
- ARID2 | c.2809C>T p.Q937* | Nonsense Mutation (SNP) | VAF 55/135 reads (41%) | catalogued as COSV57595975; called by muse, varscan2
- ARID2 | c.2881C>T p.Q961* | Nonsense Mutation (SNP) | VAF 38/86 reads (44%) | catalogued as COSV57595985; called by muse, varscan2
- ARID5B | c.2891G>T p.G964V | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV54414257; called by muse, mutect2, varscan2
- ARL15 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV72288878; called by muse, mutect2, varscan2
- ARMC4 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV59456008; called by muse, mutect2, varscan2
- ARMCX3 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV57869690; called by muse, mutect2, varscan2
- ART1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as rs1363017030, COSV51702878; called by muse, varscan2
- ART3 | c.549T>A p.F183L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV61913082; called by muse, mutect2, varscan2
- ASAH2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 141/302 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs761627134, COSV61482768; called by muse, mutect2, varscan2
- ASGR1 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.5); PolyPhen probably damaging (1); catalogued as COSV52648377; called by muse, varscan2
- ASPN | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 96/107 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1233867463, COSV65015842; called by muse, mutect2, varscan2
- ASXL3 | c.5095G>A p.A1699T | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs376961486; called by muse, mutect2, varscan2
- ATAD1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57755769; called by muse, mutect2, varscan2
- ATAD5 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58972048; called by muse, mutect2, varscan2
- ATP2B2 | c.2293G>A p.E765K (on ENST00000352432; = p.E731K on NM_001683.5) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV59489081; called by muse, mutect2, varscan2
- ATP5PO | c.579T>A p.Y193* | Nonsense Mutation (SNP) | VAF 44/78 reads (56%) | catalogued as COSV51707950; called by muse, mutect2, varscan2
- ATP7A | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58442713; called by muse, mutect2, varscan2
- ATP9B | c.3323C>T p.T1108I | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1394662699, COSV56945987; called by muse, mutect2, varscan2
- B3GALNT1 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57579630; called by muse, mutect2, varscan2
- B3GLCT | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914062573, COSV58453355; called by muse, mutect2, varscan2
- BAAT | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52287142; called by muse, mutect2, varscan2
- BAIAP3 | c.791T>G p.V264G | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60977244; called by muse, mutect2, varscan2
- BCAS3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753613820, COSV66770082; called by muse, mutect2, varscan2
- BDP1 | c.3704C>T p.S1235F | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV62428909; called by muse, mutect2, varscan2
- BEND2 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV66215029; called by muse, mutect2, varscan2
- BIN2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as COSV57203584; called by muse, mutect2, varscan2
- BMP5 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1174900882, COSV63701001; called by muse, mutect2, varscan2
- BMS1 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV65732881; called by muse, mutect2, varscan2
- BNC1 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.36); catalogued as COSV61756495; called by muse, mutect2, varscan2
- BNIP5 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV71325278; called by muse, mutect2, varscan2
- BOD1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV53632071; called by muse, mutect2, varscan2
- BOD1L1 | c.7160C>T p.P2387L | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1209837163, COSV50006542; called by muse, mutect2, varscan2
- BRCC3 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.207); catalogued as COSV57461816; called by muse, mutect2, varscan2
- BRINP3 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66513568; called by muse, mutect2, varscan2
- BRINP3 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 545/576 reads (95%) | catalogued as COSV66513576, COSV66524701; called by muse, mutect2, varscan2
- BRK1 | c.117C>T p.F39= | Splice Region (SNP) | VAF 25/45 reads (56%) | catalogued as rs923766988, COSV56541491; called by muse, mutect2, varscan2
- BRWD3 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs1085307469, COSV64743907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV64743915; called by muse, mutect2, varscan2
- BSPRY | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV99444845; called by muse, mutect2, varscan2
- BTN3A3 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372318760; called by muse, mutect2, varscan2
- C10orf71 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as COSV60504430; called by muse, mutect2, varscan2
- C12orf42 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV59378868; called by muse, varscan2
- C12orf42 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs868215930, COSV59378876; called by muse, varscan2
- C1QTNF3 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 35/81 reads (43%) | catalogued as rs754470860, COSV51467668; called by muse, mutect2, varscan2
- C1orf74 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV50550476; called by muse, mutect2, varscan2
- C6 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54704879; called by muse, mutect2, varscan2
- C8B | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs754719995, COSV64776492; called by muse, mutect2, varscan2
- CA4 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56280817, COSV99958294; called by muse, mutect2, varscan2
- CA9 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775685259, COSV65674985; called by muse, varscan2
- CACNA1E | c.1418T>G p.V473G | Missense Mutation (SNP) | VAF 148/152 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV62382196; called by muse, varscan2
- CACNA1E | c.3224C>T p.P1075L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV62382207; called by muse, mutect2
- CACNA1S | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 64/65 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62936125; called by muse, mutect2, varscan2
- CACNA2D3 | c.985A>C p.K329Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV55513754; called by muse, mutect2, varscan2
- CACNG2 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as COSV55632110; called by muse, varscan2
- CADM3 | c.604G>A p.D202N (on ENST00000368125 / NM_001127173.3; = p.D236N on NM_021189.5) | Missense Mutation (SNP) | VAF 90/94 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63683671; called by muse, mutect2, varscan2
- CARD11 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV62753981; called by muse, mutect2, varscan2
- CASR | c.1927G>A p.G643R (on ENST00000490131; = p.G720R on NM_000388.4) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56134198; called by muse, mutect2
- CATSPERB | c.2524T>G p.F842V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56422195; called by muse, mutect2, varscan2
- CBFA2T2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV60073018; called by muse, mutect2, varscan2
- CCDC141 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV55368838; called by muse, mutect2, varscan2
- CCDC150 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); catalogued as COSV55871683; called by muse, mutect2, varscan2
- CCDC178 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV55759474; called by muse, mutect2, varscan2
- CCDC180 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 6/7 reads (86%) | SIFT tolerated (0.51); PolyPhen benign (0.104); catalogued as COSV63826807; called by muse, mutect2
- CCDC38 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60182179, COSV60183811; called by muse, mutect2, varscan2
- CCDC39 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56478647; called by muse, mutect2, varscan2
- CCDC6 | c.1423T>C p.*475Qext*6 | Nonstop Mutation (SNP) | VAF 50/132 reads (38%) | catalogued as COSV54054601; called by muse, mutect2, varscan2
- CCDC63 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57526812; called by muse, mutect2, varscan2
- CCDC8 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.148); catalogued as COSV56772176; called by muse, mutect2, varscan2
- CCDC92 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV104379765, COSV53018573; called by muse, mutect2, varscan2
- CCNJ | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56441650; called by muse, mutect2, varscan2
- CCP110 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66816502; called by muse, mutect2, varscan2
- CCR8 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58336735; called by muse, mutect2, varscan2
- CD109 | c.3161C>T p.T1054I | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV54645358; called by muse, mutect2, varscan2
- CD163 | c.3469T>A p.*1157Kext*7 | Nonstop Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV63129445; called by muse, mutect2, varscan2
- CD163 | c.3095C>T p.S1032L | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV63129451; called by muse, mutect2, varscan2
- CD28 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV60729998; called by muse, mutect2, varscan2
- CDH10 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050393, COSV52570059; called by muse, mutect2, varscan2
- CDH12 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 55/115 reads (48%) | catalogued as rs773228403, COSV66388324, COSV66420863; called by muse, mutect2, varscan2
- CDH13 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.46); PolyPhen probably damaging (1); catalogued as rs1567514996, COSV51791238; called by muse, mutect2, varscan2
- CDH6 | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV54064058, COSV99418406; called by muse, mutect2, varscan2
- CDH7 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59881556; called by muse, mutect2, varscan2
- CDH9 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs762037380, COSV50252306, COSV50267855; called by muse, mutect2, varscan2
- CDHR1 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60559517; called by muse, mutect2, varscan2
- CDHR2 | c.2932G>C p.G978R | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56134639; called by muse, mutect2, varscan2
- CDHR5 | c.1649G>A p.G550E (on ENST00000358353 / NM_001171968.2; = p.G556E on NM_021924.5) | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.824); catalogued as COSV57641371; called by muse, mutect2, varscan2
- CEACAM16 | c.409G>C p.A137P | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV69186131; called by muse, mutect2, varscan2
- CEACAM20 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 164/376 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1018655741, COSV57600790; called by muse, mutect2, varscan2
- CEACAM7 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV50072479; called by muse, mutect2, varscan2
- CEL | c.689C>T p.P230L (on ENST00000673714; = p.P227L on NM_001807.6) | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV60826280; called by muse, mutect2, varscan2
- CENPC | c.1325A>T p.E442V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV56621196; called by muse, mutect2, varscan2
- CEP112 | c.2394G>T p.K798N | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67136295; called by mutect2, varscan2
- CEP68 | c.357G>A p.Q119= | Splice Region (SNP) | VAF 37/100 reads (37%) | catalogued as COSV53123420; called by muse, mutect2, varscan2
- CEP85 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 65/71 reads (92%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs747760374, COSV53327055; called by muse, mutect2, varscan2
- CER1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV66602903; called by muse, mutect2, varscan2
- CETN2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 87/140 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs782779595, COSV64743193; called by muse, mutect2, varscan2
- CFAP100 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.311); catalogued as rs1560083184, COSV61502356; called by muse, mutect2, varscan2
- CFAP206 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1251263246, COSV51532553; called by muse, varscan2
- CFAP221 | c.2165G>A p.S722N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV54653977; called by muse, mutect2, varscan2
- CFAP43 | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.166); catalogued as COSV53376279; called by muse, mutect2, varscan2
- CFAP65 | c.317G>A p.S106N (on ENST00000341552 / NM_194302.4; = p.S41N on NM_152389.4) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs1267095495, COSV55389353; called by muse, mutect2, varscan2
- CFAP69 | c.491T>A p.V164D | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV60184158; called by muse, mutect2, varscan2
- CFAP77 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs779410537, COSV58007198; called by muse, mutect2, varscan2
- CFTR | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1417904716, CD941634, COSV50040996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGREF1 | c.749G>A p.G250E (on ENST00000260595; = p.G267E on NM_006569.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV99565063; called by muse, varscan2
- CHD5 | c.3742G>A p.D1248N | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV99313033; called by muse, mutect2, varscan2
- CHD6 | c.7495C>T p.P2499S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64688393; called by muse, mutect2, varscan2
- CHGB | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV66759443; called by muse, mutect2, varscan2
- CHL1 | c.917G>A p.G306E (on ENST00000397491 / NM_001253387.1; = p.G322E on NM_006614.4) | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56586497; called by muse, mutect2, varscan2
- CHRM2 | c.1327T>A p.C443S | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57765415; called by muse, mutect2, varscan2
- CHRNA5 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183719313, COSV55137477; called by muse, mutect2, varscan2
- CHST15 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199887555, COSV60560141, COSV60560330; called by muse, mutect2, varscan2
- CILP2 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV52272524; called by muse, mutect2
- CLCA4 | c.2044G>A p.G682R | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as COSV99760340; called by muse, varscan2
- CLCA4 | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV55366552; called by muse, varscan2
- CLDN10 | c.157T>G p.C53G | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54823277; called by muse, mutect2, varscan2
- CLEC3B | c.498T>A p.D166E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56109428; called by muse, mutect2, varscan2
- CLPB | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 228/496 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53627323; called by muse, mutect2, varscan2
- CLVS1 | c.551T>A p.I184K | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV57970589; called by muse, mutect2, varscan2
- CMKLR1 | c.771G>T p.K257N (on ENST00000312143 / NM_001142344.2; = p.K255N on NM_004072.3) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56436314; called by muse, varscan2
- CNBD2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100839063; called by muse, mutect2, varscan2
- CNGA3 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs751916521, COSV55622116; called by muse, mutect2, varscan2
- CNGA4 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 57/141 reads (40%) | catalogued as rs1198682165, COSV66005039; called by muse, mutect2, varscan2
- CNNM2 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV63996892; called by muse, mutect2, varscan2
- CNR2 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 53/55 reads (96%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV65692210; called by muse, mutect2, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by muse, mutect2, varscan2
- CNTNAP2 | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs143879959, COSV62265209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.3050C>T p.P1017L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV70472805; called by muse, mutect2, varscan2
- COG1 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55428231; called by muse, mutect2, varscan2
- COL11A1 | c.3713C>T p.P1238L | Missense Mutation (SNP) | VAF 152/165 reads (92%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV62172928; called by muse, varscan2
- COL13A1 | c.1489G>A p.G497R (on ENST00000398978 / NM_001130103.2; = p.G440R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100637376; called by muse, mutect2, varscan2
- COL15A1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as rs1244997968, COSV66641341; called by muse, mutect2, varscan2
- COL18A1 | c.4490G>A p.G1497E (on ENST00000359759 / NM_130444.3; = p.G1262E on NM_030582.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs1443457119, COSV60586466; called by muse, varscan2
- COL1A2 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as COSV51952895, COSV51963325; called by muse, mutect2, varscan2
- COL28A1 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV68080541; called by muse, mutect2, varscan2
- COL28A1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs746571443, COSV68080546; called by muse, mutect2, varscan2
- COL4A1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV65421385; called by muse, mutect2, varscan2
- COL4A4 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV61629537; called by muse, varscan2
- COL5A3 | c.4387G>A p.G1463S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53406198; called by muse, mutect2, varscan2
- COL5A3 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.92); PolyPhen benign (0.444); catalogued as COSV53406210; called by muse, mutect2, varscan2
- COL6A6 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as rs889564954, COSV62017697; called by muse, mutect2, varscan2
- COL7A1 | c.7444G>A p.E2482K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV60391153; called by muse, mutect2, varscan2
- CORIN | c.2077T>A p.S693T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV56686088; called by mutect2, varscan2
- CORIN | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs866555206, COSV56686099; called by muse, mutect2, varscan2
- CPEB2 | c.2785C>T p.Q929* | Nonsense Mutation (SNP) | VAF 56/129 reads (43%) | catalogued as COSV52589288; called by muse, mutect2, varscan2
- CPNE9 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV56067615, COSV56068980; called by muse, mutect2, varscan2
- CR2 | c.1890T>G p.C630W | Missense Mutation (SNP) | VAF 140/146 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65506036; called by muse, varscan2
- CRB1 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 258/268 reads (96%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs757279881, HM060031, COSV66328646; called by muse, mutect2, varscan2
- CRB2 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0.05); PolyPhen benign (0.433); catalogued as COSV63501695; called by muse, mutect2, varscan2
- CRYBG2 | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.024); catalogued as COSV57483749; called by muse, mutect2, varscan2
- CSF2RA | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV62623485; called by muse, mutect2, varscan2
- CSF2RB | c.2579C>T p.P860L | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99453504; called by muse, mutect2, varscan2
- CSMD1 | c.10166C>T p.T3389I (on ENST00000520002; = p.T3388I on NM_033225.6) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59281782, COSV59329181; called by muse, mutect2, varscan2
- CSMD2 | c.10423G>A p.E3475K | Missense Mutation (SNP) | VAF 191/200 reads (96%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as rs760761552, COSV53879213; called by muse, mutect2, varscan2
- CSMD2 | c.6614C>T p.S2205F | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT tolerated (0.24); PolyPhen benign (0.093); catalogued as COSV53879239; called by muse, mutect2, varscan2
- CSMD2 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 70/76 reads (92%) | SIFT tolerated (0.48); PolyPhen benign (0.411); catalogued as rs530154163, COSV53879276; called by muse, mutect2, varscan2
- CSMD3 | c.8254C>T p.P2752S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52103205; called by muse, mutect2, varscan2
- CSNK1G1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.946); catalogued as rs1449629917, COSV57306773; called by muse, mutect2, varscan2
- CSPG4 | c.4102C>T p.P1368S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57890186; called by muse, mutect2, varscan2
- CTNNA2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs766350655, COSV63546883; called by muse, mutect2, varscan2
- CUBN | c.9911C>T p.S3304F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV64707852; called by muse, mutect2, varscan2
- CUBN | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64707856; called by muse, mutect2, varscan2
- CUL9 | c.6225C>A p.S2075R | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV99335099; called by muse, mutect2, varscan2
- CUL9 | c.6226C>T p.P2076S | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV99335100; called by muse, mutect2, varscan2
- CUX2 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV55632376; called by muse, mutect2, varscan2
- CUX2 | c.3821A>T p.E1274V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV99919145; called by mutect2, varscan2
- CXCR2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1298311873, COSV59279763; called by muse, mutect2, varscan2
- CXCR3 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65461532; called by muse, mutect2, varscan2
- CYBB | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs868992616, CD012000, CD044971, COSV66084754; called by muse, mutect2, varscan2
- CYP11B1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52824823; called by muse, mutect2, varscan2
- CYP2C9 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV53246436; called by muse, mutect2, varscan2
- CYP3A5 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs200980665, COSV56118491; called by muse, mutect2, varscan2
- CYP4F11 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56125604, COSV56129330; called by muse, mutect2, varscan2
- CYP4V2 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554075115, COSV66504950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAB1 | c.1618G>A p.D540N (on ENST00000371231; = p.D507N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/89 reads (94%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.917); catalogued as COSV64690058, COSV64690164; called by muse, mutect2, varscan2
- DAB2 | c.1599G>A p.M533I | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57912345; called by muse, mutect2, varscan2
- DACH1 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV57489576; called by muse, mutect2, varscan2
- DACT3 | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as COSV56258326; called by muse, mutect2, varscan2
- DCAF12L2 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV63580247; called by muse, mutect2, varscan2
- DCC | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs867121344, COSV59084449; called by muse, mutect2, varscan2
- DCC | c.3910G>A p.G1304R | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.222); catalogued as COSV71425751, COSV71433082; called by muse, mutect2, varscan2
- DCDC1 | c.2057G>A p.S686N | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs373385665; called by muse, mutect2, varscan2
- DCLK1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55171630; called by muse, mutect2, varscan2
- DCLK3 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69362182; called by muse, mutect2, varscan2
- DCLK3 | c.1443A>T p.E481D | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69362183; called by muse, mutect2, varscan2
- DCLK3 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV69362187; called by muse, mutect2, varscan2
- DDC | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.273); catalogued as rs1377396127, COSV63563690; called by muse, mutect2, varscan2
- DDN | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV70404106; called by muse, mutect2, varscan2
- DDX4 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV61753399; called by muse, mutect2, varscan2
- DEFA5 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs866047660, COSV57961915; called by muse, mutect2, varscan2
- DEFB119 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53619604; called by muse, mutect2, varscan2
- DEGS2 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 48/95 reads (51%) | catalogued as COSV59783358; called by muse, mutect2, varscan2
- DENND3 | c.2455G>A p.D819N | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs112917986, COSV52800841; called by muse, mutect2, varscan2
- DEPP1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as COSV53573362; called by muse, mutect2, varscan2
- DHX15 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61025627; called by muse, mutect2, varscan2
- DHX40 | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV52065979; called by mutect2, varscan2
- DIAPH2 | c.2843C>T p.T948I | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV61260453; called by muse, mutect2, varscan2
- DIP2A | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs370131608; called by muse, mutect2, varscan2
- DIP2A | c.4430C>T p.S1477F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59471862; called by muse, mutect2, varscan2
- DISP3 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 55/61 reads (90%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as COSV53820255; called by muse, mutect2, varscan2
- DKC1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV65777011; called by muse, mutect2, varscan2
- DLGAP3 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 91/96 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52391401; called by muse, mutect2, varscan2
- DMD | c.8188G>A p.G2730R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV58891776; called by muse, mutect2, varscan2
- DMTN | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV56111092; called by muse, mutect2, varscan2
- DMXL2 | c.4279C>T p.P1427S | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51840769, COSV99196004; called by muse, mutect2, varscan2
- DNA2 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64427368; called by muse, mutect2, varscan2
- DNAH10 | c.8701G>A p.E2901K (on ENST00000409039; = p.E2840K on NM_207437.3) | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV68987852; called by muse, mutect2, varscan2
- DNAH11 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 95/198 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as COSV60939823; called by muse, mutect2, varscan2
- DNAH17 | c.12730G>A p.E4244K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs967666308, COSV53143299; called by mutect2, varscan2
- DNAH17 | c.7787G>A p.G2596D | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV67749800; called by muse, mutect2, varscan2
- DNAH7 | c.8405C>T p.S2802L | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV56750064; called by muse, mutect2, varscan2
- DNAH7 | c.6358G>A p.D2120N | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV56751887; called by muse, mutect2, varscan2
- DNAH7 | c.5869C>T p.R1957* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as rs149212659, COSV56751897; called by muse, mutect2, varscan2
- DNAH8 | c.4948C>T p.P1650S | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs761136243, COSV59424967; called by muse, mutect2, varscan2
- DNAI2 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as rs368063114; called by muse, mutect2, varscan2
- DNAJA2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV100398919, COSV57694340; called by muse, mutect2, varscan2
- DOCK2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV56942150; called by muse, mutect2, varscan2
- DOCK3 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as COSV56502844; called by muse, mutect2, varscan2
- DOT1L | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs773452337, COSV67107958; called by muse, mutect2, varscan2
- DPF3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV63498695; called by muse, mutect2, varscan2
- DPP10 | c.1667T>G p.M556R | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59664756; called by muse, mutect2, varscan2
- DPP8 | c.1175C>T p.S392F (on ENST00000341861 / NM_001320875.2; = p.S376F on NM_017743.6) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV55675962; called by muse, mutect2, varscan2
- DPPA3 | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 106/226 reads (47%) | catalogued as COSV61502717; called by muse, varscan2
- DRC7 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV61052943; called by muse, mutect2, varscan2
- DRGX | c.251G>A p.R84K | Missense Mutation (SNP) | VAF 109/219 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65135759; called by muse, mutect2, varscan2
- DRP2 | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs34562102, COSV101235283, COSV67870604; called by muse, mutect2, varscan2
- DSCAM | c.1975C>T p.L659F | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68020872, COSV68035338; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 124/299 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DSG3 | c.2891G>A p.R964K | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV57124185; called by muse, mutect2, varscan2
- DSG4 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs74896702, COSV57388260, COSV57388919; called by muse, mutect2, varscan2
- DSP | c.5615C>T p.S1872F | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as COSV65791105; called by muse, mutect2, varscan2
- DYDC2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1554848062, COSV55471697; called by muse, mutect2, varscan2
- DYNC1H1 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1429466018, COSV64134344; called by muse, mutect2, varscan2
- DYTN | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1227006544, COSV71751536; called by muse, mutect2, varscan2
- EFHC1 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368992606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFR3A | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as rs770587283, COSV54453226; called by muse, mutect2, varscan2
- EIF4E1B | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53779191; called by muse, mutect2, varscan2
- EIF5A2 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55542426; called by muse, mutect2, varscan2
- ELAC2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV62031716; called by muse, mutect2, varscan2
- ELFN2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs200557041, COSV68743789; called by muse, mutect2, varscan2
- ELN | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52706940; called by muse, mutect2, varscan2
- ELOA3C | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs778787662, COSV55293512; called by muse, mutect2, varscan2
- EML1 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51741488, COSV51742812; called by muse, mutect2, varscan2
- EML2 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV55597491; called by muse, mutect2, varscan2
- ENOX2 | c.1207G>A p.E403K (on ENST00000338144 / NM_001382520.1; = p.E374K on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.345); catalogued as COSV57647423; called by muse, mutect2
- EP400 | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57762632; called by muse, varscan2
- EPB41L2 | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV61353102; called by muse, mutect2, varscan2
- EPHA2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 67/71 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs749273208, COSV64452086; called by muse, varscan2
- EPHA6 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 100/257 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67558967; called by muse, mutect2, varscan2
- EPHA6 | c.2653G>A p.D885N (on ENST00000389672 / NM_001080448.3; = p.D277N on NM_173655.4) | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV67558974; called by muse, mutect2, varscan2
- EPPK1 | c.5339G>A p.R1780K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73260802; called by muse, mutect2, varscan2
- ERAP2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV65938668; called by muse, mutect2, varscan2
- ERBB2 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV54063107; called by muse, mutect2, varscan2
- ETNK1 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV56883723; called by muse, mutect2, varscan2
- EVC | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs148823298, COSV53829222; called by muse, mutect2, varscan2
- EVI5L | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as COSV54483790, COSV99562789; called by muse, mutect2, varscan2
- EVPL | c.4597G>A p.E1533K | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56907352; called by muse, mutect2, varscan2
- EXPH5 | c.4157G>A p.G1386D | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV56198890; called by muse, mutect2, varscan2
- EYS | c.1707T>A p.D569E | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT tolerated (0.89); PolyPhen benign (0.432); catalogued as COSV60976490; called by muse, varscan2
- F8 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64269762; called by muse, mutect2, varscan2
- FAAH2 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV66505263; called by muse, mutect2, varscan2
- FAM131B | c.186G>A p.G62= | Splice Region (SNP) | VAF 7/24 reads (29%) | catalogued as COSV68125502; called by muse, mutect2
- FAM135B | c.4035G>A p.M1345I | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52705063; called by muse, mutect2, varscan2
- FAM135B | c.3776C>T p.T1259I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV52705078; called by muse, mutect2, varscan2
- FAM135B | c.2387C>A p.A796D | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.058); catalogued as COSV52705118; called by muse, mutect2, varscan2
- FAM166C | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); catalogued as COSV56599106; called by muse, mutect2, varscan2
- FAM169A | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57187496; called by muse, mutect2, varscan2
- FAM47C | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV63723613; called by muse, mutect2, varscan2
- FAM83B | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415941389, COSV60919333; called by muse, varscan2
- FAM83B | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV60919348; called by muse, varscan2
- FAM83C | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV65581996; called by muse, mutect2, varscan2
- FASTK | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (0.96); PolyPhen benign (0.062); catalogued as COSV52539071; called by muse, mutect2, varscan2
- FAT2 | c.7216C>T p.P2406S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55813187; called by muse, mutect2, varscan2
- FAT4 | c.14635G>A p.D4879N | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58671569; called by muse, mutect2, varscan2
- FBLN5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV50902089, COSV50905990; called by muse, mutect2, varscan2
- FBXL13 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV57534859; called by muse, mutect2, varscan2
- FBXO40 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as rs775675600, COSV57521932; called by muse, mutect2, varscan2
- FBXO47 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV100960577, COSV65241164; called by muse, mutect2, varscan2
- FCGBP | c.11383G>A p.D3795N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs371784970; called by mutect2, varscan2
- FCRL6 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 63/64 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs780674077, COSV58939935; called by muse, mutect2, varscan2
- FGA | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs763555716, COSV57393105; called by muse, varscan2
- FGD2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs745324102, COSV51462285, COSV51463688; called by muse, mutect2, varscan2
- FGD2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs762784794, COSV51462297; called by muse, mutect2, varscan2
- FGD5 | c.2962G>A p.D988N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53237275, COSV53245932; called by muse, mutect2, varscan2
- FGD5 | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs1303571738, COSV53240759; called by muse, mutect2, varscan2
- FGF3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs868995912, COSV61925249; called by muse, mutect2, varscan2
- FGF5 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.229); catalogued as COSV56889090; called by muse, mutect2, varscan2
- FGF9 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66644082; called by muse, mutect2, varscan2
- FHL1 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV61779707; called by muse, mutect2, varscan2
- FIBIN | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs768108138, COSV59412418; called by muse, mutect2, varscan2
- FLRT2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58136250; called by muse, mutect2, varscan2
- FLRT2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs1219460941, COSV58136260; called by muse, mutect2, varscan2
- FLT3 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54044006, COSV54070796; called by muse, mutect2, varscan2
- FMR1NB | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.415); catalogued as COSV63272652; called by muse, mutect2, varscan2
- FNBP1L | c.513C>T p.A171= | Splice Region (SNP) | VAF 12/14 reads (86%) | catalogued as COSV53091358; called by muse, mutect2, varscan2
- FOXK2 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV100081926; called by muse, mutect2, varscan2
- FOXL2NB | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.552); catalogued as rs764249769, COSV57725580; called by muse, mutect2, varscan2
- FOXO1 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV65425172; called by muse, mutect2, varscan2
- FRAS1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53589152; called by muse, mutect2, varscan2
- FRAS1 | c.6070C>T p.Q2024* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99349958; called by mutect2, varscan2
- FREM1 | c.3718G>A p.D1240N | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66517806; called by muse, mutect2, varscan2
- FRMPD2 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs912294812, COSV59715128; called by muse, mutect2, varscan2
- FRMPD4 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.923); catalogued as rs1178348008, COSV66211327; called by muse, mutect2, varscan2
- FSCB | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.546); catalogued as COSV61216535; called by muse, varscan2
- FSIP2 | c.19982G>A p.R6661Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs376528278; called by mutect2, varscan2
- FUT6 | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV54604455; called by muse, mutect2, varscan2
- FYB2 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 69/73 reads (95%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV58582899; called by muse, mutect2, varscan2
- FYB2 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 192/206 reads (93%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs768309203, COSV58582905, COSV58583687; called by muse, varscan2
- FZD10 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as COSV57472132; called by muse, mutect2, varscan2
- GABRA3 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 166/281 reads (59%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.503); catalogued as rs868775494, COSV64795226; called by muse, mutect2, varscan2
- GALNT14 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs145602304; called by muse, mutect2, varscan2
- GALR1 | c.669C>T p.V223= | Splice Region (SNP) | VAF 34/92 reads (37%) | catalogued as rs1232424258, COSV55315847; called by muse, mutect2, varscan2
- GAS2 | c.357G>A p.W119* | Nonsense Mutation (SNP) | VAF 38/81 reads (47%) | catalogued as COSV53404447; called by muse, mutect2, varscan2
- GBX1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770390765, COSV52546606; called by muse, mutect2, varscan2
- GCLC | c.856C>T p.P286S (on ENST00000643939; = p.P284S on NM_001498.4) | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV57593667; called by muse, mutect2, varscan2
- GCNA | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 110/260 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); catalogued as rs761216831, COSV65465846; called by muse, varscan2
- GCSAML | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 118/119 reads (99%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV63577066, COSV63578013; called by muse, mutect2, varscan2
- GDPGP1 | c.890C>G p.P297R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV61575602; called by muse, mutect2, varscan2
- GGT1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1198539739, COSV50638017; called by muse, mutect2, varscan2
- GK2 | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 51/113 reads (45%) | catalogued as COSV62626092; called by muse, mutect2, varscan2
- GLRA3 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs980137134, COSV56857776, COSV99927029; called by muse, mutect2
- GLRB | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV52412919; called by muse, mutect2, varscan2
- GLYATL1 | c.292A>G p.K98E (on ENST00000317391 / NM_001354699.1; = p.K129E on NM_080661.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.727); catalogued as COSV55607131; called by muse, mutect2, varscan2
- GLYATL2 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54848971; called by muse, mutect2, varscan2
- GPCPD1 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1422762261, COSV66830844; called by muse, mutect2, varscan2
- GPM6B | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 136/268 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); catalogued as COSV57421332, COSV57421674; called by muse, mutect2, varscan2
- GPR155 | c.1508G>A p.G503E | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55037291; called by muse, mutect2, varscan2
- GPR158 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV66265373; called by muse, mutect2, varscan2
- GPR174 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52131456; called by muse, mutect2, varscan2
- GPRASP1 | c.3543G>A p.M1181I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV64354771; called by muse, mutect2, varscan2
- GPRIN1 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV56134642; called by muse, mutect2, varscan2
- GPRIN1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV56134654; called by muse, mutect2, varscan2
- GRAMD2A | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs1286706203, COSV59032675; called by muse, mutect2, varscan2
- GRIA1 | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as COSV53589094, COSV53597833; called by muse, mutect2, varscan2
- GRIA3 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52049378; called by muse, mutect2, varscan2
- GRIA4 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56882122; called by muse, mutect2, varscan2
- GRID2 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as rs561375793, COSV56173397, COSV56284077; called by mutect2, varscan2
- GRM3 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467226; called by muse, mutect2
- GRM6 | c.2197G>A p.V733M | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV51433697; called by muse, mutect2, varscan2
- GRM8 | c.2616A>C p.K872N | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV58801771; called by muse, mutect2, varscan2
- GRXCR1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs569193097, CM153970, COSV67670071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUCA1C | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs146701862; called by muse, mutect2, varscan2
- GUCY1A2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs753774502, COSV56477850; called by muse, mutect2, varscan2
- GUCY2F | c.2947C>T p.L983F | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV54298423; called by muse, mutect2, varscan2
- HAPLN1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57145295, COSV57150307; called by muse, varscan2
- HAUS2 | c.644A>G p.D215G | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.079); catalogued as rs760061530, COSV52999099; called by muse, mutect2, varscan2
- HAVCR2 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 323/676 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.177); catalogued as COSV57151766; called by muse, mutect2, varscan2
- HCAR1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs757909237, COSV63671357; called by muse, mutect2, varscan2
- HCLS1 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57521938; called by muse, mutect2, varscan2
- HCRTR2 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs865812739, COSV63793796; called by muse, mutect2, varscan2
- HECTD4 | c.4970G>A p.C1657Y | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66386688; called by muse, mutect2, varscan2
- HECW2 | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53648466, COSV53662828; called by muse, mutect2, varscan2
- HEG1 | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs565291346, COSV60759310; called by muse, mutect2, varscan2
- HK3 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52836893; called by muse, mutect2, varscan2
- HLA-DMB | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV66870579; called by muse, mutect2, varscan2
- HLA-DQA1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58237164; called by muse, mutect2, varscan2
- HMCN1 | c.10183G>A p.G3395R | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415556754, COSV54877119; called by muse, mutect2, varscan2
- HMG20A | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV60311321; called by muse, mutect2, varscan2
- HMGB4 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 97/106 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53879295; called by muse, mutect2, varscan2
- HMGN5 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100814786, COSV63916332; called by muse, mutect2, varscan2
- HMGXB4 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs538821671, COSV53332788; called by muse, varscan2
- HNF4G | c.429G>A p.M143I (on ENST00000354370 / NM_001330561.2; = p.M190I on NM_004133.5) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.353); catalogued as COSV62965786; called by muse, mutect2, varscan2
- HOGA1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV65706252; called by muse, mutect2, varscan2
- HOXC13 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as rs1450404212, COSV54497991; called by muse, mutect2, varscan2
- HPS4 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV61102511; called by muse, varscan2
- HR | c.2992C>T p.R998W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs150573552; called by muse, mutect2, varscan2
- HRG | c.1430T>G p.F477C | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51643995; called by muse, mutect2, varscan2
- HS3ST3A1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV52372768; called by muse, mutect2, varscan2
- HSD11B2 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV52096765; called by muse, mutect2, varscan2
- HSF5 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60415147, COSV60416873; called by muse, mutect2, varscan2
- HSPG2 | c.9011C>T p.S3004F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1049346014, COSV65932695; called by muse, varscan2
- HTRA3 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745703718, COSV56469261; called by muse, mutect2, varscan2
- HYDIN | c.5722G>A p.E1908K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59263226; called by mutect2, varscan2
- IARS1 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as COSV65113976; called by muse, mutect2, varscan2
- IBSP | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as rs144185482; called by muse, mutect2, varscan2
- IFITM2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as rs368808923; called by muse, mutect2, varscan2
- IGF2BP3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs764971109, COSV51679803; called by muse, mutect2, varscan2
- IGFLR1 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV99495014; called by muse, mutect2, varscan2
- IGHV1-24 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs369101855; called by muse, mutect2, varscan2
- IGHV2-5 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1555425495; called by muse, mutect2, varscan2
- IGHV4-39 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs200099545; called by muse, mutect2, varscan2
- IGLV4-3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs1386507753; called by muse, mutect2, varscan2
- IGSF10 | c.7586G>A p.R2529Q | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs146905174, COSV56368510; called by muse, mutect2, varscan2
- IL17RD | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV56335007, COSV99576528; called by muse, mutect2, varscan2
- IL17RE | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs752148163, COSV55966605; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.419); catalogued as rs752058980, COSV61143008; called by muse, mutect2, varscan2
- IL1RL2 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as rs866058726, COSV51812942, COSV51816541; called by muse, mutect2, varscan2
- INPPL1 | c.1967C>T p.S656F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs1208152317, COSV53353202; called by muse, mutect2, varscan2
- IPO11 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57571976; called by muse, mutect2, varscan2
- IQCE | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV58076474; called by muse, mutect2, varscan2
- IRF8 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | catalogued as COSV51896661; called by muse, mutect2, varscan2
- IRS4 | c.1675G>A p.G559S | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV64532650, COSV64534261, COSV64535000; called by muse, mutect2, varscan2
- ITGA5 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53215536, COSV53219093; called by muse, varscan2
- ITGAL | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63320061; called by muse, mutect2, varscan2
- ITGAX | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51641485; called by muse, mutect2, varscan2
- ITGB4 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52321836; called by muse, varscan2
- ITGB4 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 24/59 reads (41%) | catalogued as COSV52321853; called by muse, mutect2, varscan2
- ITGB5 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56146587; called by mutect2, varscan2
- ITGB5 | c.943-1G>A p.X315_splice | Splice Site (SNP) | VAF 38/110 reads (35%) | catalogued as COSV56152388, COSV99950500; called by muse, mutect2, varscan2
- ITGB8 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.02); catalogued as COSV56004901; called by muse, mutect2, varscan2
- ITIH5 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV53659948; called by muse, mutect2, varscan2
- ITPR1 | c.7799A>G p.K2600R (on ENST00000354582; = p.K2545R on NM_002222.7) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV56968222; called by muse, mutect2, varscan2
- JMJD1C | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV101232416, COSV67857852; called by muse, mutect2
- KAT2A | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV56789263; called by muse, mutect2, varscan2
- KBTBD7 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV65266079; called by muse, mutect2, varscan2
- KCNAB1 | c.571G>A p.G191R (on ENST00000490337 / NM_172160.3; = p.G180R on NM_003471.3) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56741081; called by muse, mutect2, varscan2
- KCNB2 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.205); catalogued as COSV73048905; called by muse, mutect2, varscan2
- KCNH2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 86/125 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs267601413, COSV51126280; called by muse, mutect2, varscan2
- KCNK18 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV57970906; called by muse, mutect2, varscan2
- KCNMA1 | c.1340C>A p.S447Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.917); catalogued as COSV54227607, COSV54234302; called by mutect2, varscan2
- KCNMA1 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV54227657; called by muse, mutect2, varscan2
- KCNQ3 | c.2170G>A p.G724R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV101195827; called by muse, mutect2, varscan2
- KCNT2 | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 166/179 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs868285684, COSV54064318; called by muse, mutect2, varscan2
- KCTD11 | c.565G>A p.E189K (on ENST00000333751 / NM_001363642.1; = p.E150K on NM_001002914.2) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.025); catalogued as COSV50134075; called by muse, mutect2, varscan2
- KCTD14 | c.187T>C p.F63L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV62001043; called by muse, mutect2, varscan2
- KCTD19 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.041); catalogued as COSV58571128; called by muse, varscan2
- KDM6A | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65037155; called by muse, mutect2, varscan2
- KEL | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs943752536, COSV62333268; called by mutect2, varscan2
- KIAA0100 | c.4124C>T p.S1375F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66490567; called by muse, mutect2, varscan2
- KIAA0753 | c.288A>T p.R96S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV63816745; called by muse, mutect2, varscan2
- KIF15 | c.2468C>T p.S823L | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58158424; called by muse, mutect2, varscan2
- KIF5A | c.2993-1G>A p.X998_splice | Splice Site (SNP) | VAF 98/214 reads (46%) | catalogued as rs1416295034, COSV54051639; called by muse, mutect2, varscan2
- KIR2DL1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT tolerated (1); PolyPhen possibly damaging (0.781); catalogued as COSV52406396; called by muse, mutect2, varscan2
- KLF8 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV63847227; called by muse, mutect2, varscan2
- KLHDC7A | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 69/76 reads (91%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1216719846, COSV68768971; called by muse, mutect2, varscan2
- KLHL26 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56316168; called by muse, mutect2, varscan2
- KLKB1 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV52993878; called by muse, mutect2, varscan2
- KMO | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 44/46 reads (96%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV59362470; called by muse, mutect2, varscan2
- KMT2B | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52889400; called by muse, varscan2
- KMT2B | c.5329C>T p.R1777W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs755887571, COSV99719157; called by mutect2, varscan2
- KRT16 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56966954; called by muse, mutect2, varscan2
- KRT28 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs746857538, COSV60683602; called by muse, mutect2, varscan2
- KRT36 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV60202485; called by muse, mutect2, varscan2
- KRT4 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV53405666; called by muse, mutect2, varscan2
- KRT5 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as rs754242209, CM121638, COSV52858866; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- KRT6B | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52881874; called by mutect2, varscan2
- KRT6C | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99359896; called by muse, mutect2, varscan2
- KRT74 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59770501; called by muse, varscan2
- KRT74 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs376231388; called by muse, varscan2
- KRTAP1-3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV60335570; called by muse, varscan2
- KSR2 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs576752077, COSV56665718; called by muse, mutect2, varscan2
- KSR2 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.452); catalogued as COSV60366086; called by muse, mutect2, varscan2
- KYNU | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV51578720, COSV51579202; called by muse, mutect2, varscan2
- LAMA2 | c.6187G>A p.D2063N | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.55); PolyPhen benign (0.226); catalogued as rs187633696, COSV70338619; called by muse, varscan2
- LAMA2 | c.6344C>T p.P2115L | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70338621; called by muse, mutect2, varscan2
- LAMB2 | c.2695C>T p.H899Y | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs777651813, COSV59730778; called by muse, mutect2, varscan2
- LAMC3 | c.681G>A p.E227= | Splice Region (SNP) | VAF 55/61 reads (90%) | catalogued as rs759227811, COSV63088560; called by muse, mutect2, varscan2
- LAMP3 | c.275A>T p.K92I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV55613500; called by muse, mutect2, varscan2
- LCE1B | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 156/158 reads (99%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.124); catalogued as COSV63980050, COSV63980109; called by muse, mutect2, varscan2
- LDB3 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1348993474, COSV53937878; called by muse, mutect2, varscan2
- LDHC | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs777146300, COSV55003283; called by muse, mutect2, varscan2
- LEFTY1 | c.124A>C p.T42P | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as COSV55282175; called by muse, mutect2, varscan2
- LGALS9 | c.808C>T p.P270S (on ENST00000395473 / NM_009587.3; = p.P238S on NM_002308.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56347936; called by muse, mutect2, varscan2
- LGI2 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV66122269; called by muse, mutect2, varscan2
- LILRA4 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1385711069, COSV52490278; called by muse, mutect2, varscan2
- LILRB1 | c.595G>A p.E199K (on ENST00000427581; = p.E163K on NM_006669.6) | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV61117897; called by muse, mutect2, varscan2
- LILRB1 | c.1648G>A p.D550N (on ENST00000427581; = p.D500N on NM_006669.6) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV61115913, COSV61117763; called by mutect2, varscan2
- LILRB5 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.024); catalogued as rs759536980, COSV60254529; called by muse, mutect2, varscan2
- LIMK2 | c.1606C>G p.L536V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.896); catalogued as COSV59181352; called by muse, mutect2, varscan2
- LIPC | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as COSV100134146, COSV54420196; called by muse, mutect2, varscan2
- LIPK | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV68200610; called by muse, mutect2, varscan2
- LONRF2 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.129); catalogued as rs894221703, COSV66539333; called by muse, mutect2, varscan2
- LONRF3 | c.2186G>A p.R729Q (on ENST00000371628 / NM_001031855.3; = p.R688Q on NM_024778.5) | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs143959775, COSV59149748; called by muse, mutect2, varscan2
- LORICRIN | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 34/37 reads (92%) | PolyPhen probably damaging (0.924); catalogued as COSV64201219; called by muse, mutect2, varscan2
- LPO | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV51856830; called by muse, mutect2, varscan2
- LRBA | c.7415G>A p.R2472Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.301); catalogued as COSV63949907; called by muse, mutect2, varscan2
- LRFN2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs959343309, COSV57823890; called by muse, mutect2, varscan2
- LRFN5 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs1051039315, COSV53243316, COSV53273551; called by muse, mutect2, varscan2
- LRIG2 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV63160788; called by muse, mutect2, varscan2
- LRP1B | c.12262G>A p.A4088T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101254546; called by muse, mutect2, varscan2
- LRP1B | c.7271G>A p.G2424E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1407431766, COSV67186570; called by muse, mutect2, varscan2
- LRP1B | c.6604C>T p.L2202F | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV67186573; called by muse, mutect2, varscan2
- LRP2 | c.13114G>A p.E4372K | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as CM135275, COSV55540870; called by mutect2, varscan2
- LRRC10 | c.335A>C p.D112A | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.089); catalogued as COSV64060018; called by muse, mutect2, varscan2
- LRRC37A3 | c.4837G>A p.E1613K | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV58534282; called by muse, varscan2
- LRRC3B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV101185747, COSV67520069; called by muse, varscan2
- LRRC3B | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67520073; called by muse, varscan2
- LRRC4C | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53418262; called by muse, mutect2, varscan2
- LRRC75A | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749348067, COSV69124976; called by muse, mutect2, varscan2
- LTBP1 | c.2957G>A p.S986N (on ENST00000404816 / NM_206943.4; = p.S660N on NM_000627.4) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV63179868; called by muse, mutect2, varscan2
- LUZP2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV61195533; called by muse, mutect2, varscan2
- LYG2 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV60715231; called by muse, mutect2, varscan2
- MACC1 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 120/258 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV60540849; called by muse, mutect2, varscan2
- MAGEA4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 100/159 reads (63%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); catalogued as rs767725718, COSV52340216; called by muse, mutect2, varscan2
- MAGEC1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 110/188 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1469473688, COSV53567904; called by muse, varscan2
- MAGEC1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 132/404 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs866448898, COSV53567920; called by muse, mutect2, varscan2
- MAGEC3 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs866786468, COSV53576159; called by muse, varscan2
- MAL2 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | catalogued as COSV52659898, COSV52660806; called by muse, mutect2, varscan2
- MAP2K5 | c.1108C>T p.Q370* (on ENST00000178640 / NM_145160.3; = p.Q360* on NM_002757.4) | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV51610157; called by muse, mutect2, varscan2
- MAP3K15 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456187206, COSV58825962; called by muse, mutect2, varscan2
- MAP3K19 | c.2123G>A p.R708K | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.696); catalogued as rs1298202631, COSV59636628; called by muse, mutect2, varscan2
- MAP7 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV63417103; called by muse, mutect2, varscan2
- MAP7D2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV65525611; called by muse, mutect2, varscan2
- MAPK14 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57694661; called by muse, mutect2, varscan2
- MAPK4 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV68541020, COSV68541099; called by muse, varscan2
- MARK3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53506254; called by muse, mutect2, varscan2
- MARS2 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56570726; called by muse, mutect2, varscan2
- MATN2 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs373873113; called by muse, mutect2, varscan2
- MBD3L1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as COSV59775721; called by muse, mutect2, varscan2
- MCF2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV58477333; called by muse, mutect2, varscan2
- MCMBP | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139316442; called by muse, mutect2, varscan2
- MCOLN1 | c.1362C>T p.F454= | Splice Region (SNP) | VAF 57/130 reads (44%) | catalogued as rs780662724, COSV51173922; called by muse, mutect2, varscan2
- MDGA2 | c.3035T>A p.F1012Y (on ENST00000399232 / NM_001113498.2; = p.F714Y on NM_182830.4) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as COSV62079314; called by mutect2, varscan2
- MDGA2 | c.1300C>T p.P434S (on ENST00000399232 / NM_001113498.2; = p.P136S on NM_182830.4) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62079322; called by muse, mutect2, varscan2
- MDH1B | c.1356G>A p.Q452= | Splice Region (SNP) | VAF 24/69 reads (35%) | catalogued as COSV65588532; called by muse, mutect2, varscan2
- MECOM | c.2186G>A p.G729E (on ENST00000468789 / NM_001105078.4; = p.G917E on NM_004991.4) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV52959553; called by muse, mutect2, varscan2
- MECOM | c.1852G>A p.E618K (on ENST00000468789 / NM_001105078.4; = p.E806K on NM_004991.4) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs771184600, COSV52959566; called by muse, mutect2, varscan2
- MED1 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as COSV56122334; called by muse, mutect2, varscan2
- MED12L | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56368485, COSV99853076; called by mutect2, varscan2
- MED12L | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.48); catalogued as rs868783221, COSV56368501, COSV56385433; called by muse, mutect2, varscan2
- MED16 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.478); catalogued as COSV54123119; called by muse, mutect2
- MEOX2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.109); catalogued as COSV56287560; called by muse, mutect2, varscan2
- MEP1A | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV57917910; called by muse, mutect2, varscan2
- MEPE | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.462); catalogued as COSV63071824; called by muse, varscan2
- MGAM | c.3592C>T p.Q1198* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV72073620; called by muse, mutect2
- MID1 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV58191647; called by muse, varscan2
- MIPEP | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs149545169; called by muse, varscan2
- MITF | c.729G>C p.L243F (on ENST00000448226 / NM_006722.3; = p.L137F on NM_000248.4) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.091); catalogued as CD101995, COSV58829825; called by muse, mutect2, varscan2
- MLLT3 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV63494840; called by muse, varscan2
- MLLT6 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1460952874; called by muse, mutect2, varscan2
- MLST8 | c.890G>A p.W297* | Nonsense Mutation (SNP) | VAF 83/179 reads (46%) | catalogued as rs1347285506, COSV57031914; called by muse, mutect2, varscan2
- MLST8 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 81/178 reads (46%) | catalogued as COSV100063315; called by muse, mutect2, varscan2
- MMADHC | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57573026; called by muse, mutect2, varscan2
- MMP14 | c.1094C>G p.P365R | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61287449; called by muse, mutect2, varscan2
- MMP19 | c.1157G>A p.W386* | Nonsense Mutation (SNP) | VAF 50/112 reads (45%) | catalogued as COSV59450276; called by muse, mutect2, varscan2
- MOSPD1 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369947136, COSV66189101; called by muse, varscan2
- MPHOSPH8 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs1413333092, COSV64054281; called by muse, mutect2, varscan2
- MRGPRX1 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV57105899; called by muse, mutect2, varscan2
- MROH2B | c.4429G>A p.D1477N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV68180970; called by muse, mutect2, varscan2
- MROH2B | c.1035G>A p.E345= | Splice Region (SNP) | VAF 29/60 reads (48%) | catalogued as COSV68180980; called by muse, mutect2, varscan2
- MROH2B | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV101270697, COSV68180982; called by muse, mutect2, varscan2
- MRS2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as COSV51233854; called by muse, mutect2, varscan2
- MRTFA | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931221; called by muse, mutect2, varscan2
- MS4A1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs777259260, COSV61941653; called by muse, mutect2, varscan2
- MTMR7 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51663030, COSV51668773; called by muse, varscan2
- MTTP | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55503753; called by muse, mutect2, varscan2
- MUC16 | c.21617C>T p.S7206F | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV67444771; called by muse, mutect2, varscan2
- MUC16 | c.12899A>T p.E4300V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV101199043; called by mutect2, varscan2
- MUC16 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as rs533548881, COSV67444798; called by muse, mutect2, varscan2
- MUC17 | c.6337C>T p.P2113S | Missense Mutation (SNP) | VAF 243/444 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV60279960; called by muse, varscan2
- MUC17 | c.6881C>T p.S2294F | Missense Mutation (SNP) | VAF 247/388 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60279967; called by muse, mutect2, varscan2
- MUC5B | c.12586G>A p.D4196N | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs1372232880, COSV71590011; called by muse, mutect2, varscan2
- MUSK | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs764486887, COSV51878132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPC1 | c.301G>A p.D101N (on ENST00000550270 / NM_206820.2; = p.D126N on NM_002465.4) | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62251052; called by muse, mutect2, varscan2
- MYBPC3 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV57022981; called by muse, mutect2
- MYCBP2 | c.11818C>T p.R3940C (on ENST00000357337; = p.R3978C on NM_015057.5) | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771880861, COSV62010279; called by muse, mutect2, varscan2
- MYH1 | c.4303G>A p.D1435N | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs867955270, COSV56843055; called by muse, mutect2, varscan2
- MYH15 | c.1867A>C p.K623Q | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56304456; called by muse, mutect2, varscan2
- MYH2 | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.297); catalogued as COSV55431594; called by muse, mutect2, varscan2
- MYH4 | c.5527G>A p.G1843S | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV55112258; called by muse, mutect2, varscan2
- MYH6 | c.1292C>A p.A431E | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62447903; called by muse, mutect2, varscan2
- MYH8 | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749792075, COSV67959787, COSV67964250; called by muse, mutect2, varscan2
- MYH8 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV67959790; called by muse, mutect2, varscan2
- MYO16 | c.2658G>A p.M886I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV51777541, COSV99193685; called by muse, mutect2, varscan2
- MYO16 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 86/173 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as rs756747037, COSV62745391; called by muse, mutect2, varscan2
- MYO5B | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV53210513; called by muse, mutect2, varscan2
- MYO7A | c.3126G>A p.W1042* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV101289084; called by muse, mutect2, varscan2
- MYOM1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV55285497; called by muse, mutect2, varscan2
- MYOM2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs148337899; called by muse, varscan2
- MYOM2 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV50702205; called by muse, mutect2, varscan2
- MYOM3 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 12/12 reads (100%) | catalogued as COSV58389631; called by muse, mutect2, varscan2
- MYT1L | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.014); catalogued as COSV67708295; called by muse, mutect2, varscan2
- NALCN | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51917910; called by muse, mutect2, varscan2
- NAP1L2 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); catalogued as rs751106132, COSV65172167; called by muse, mutect2, varscan2
- NAXD | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV59393545; called by muse, mutect2, varscan2
- NBAS | c.3406C>T p.H1136Y | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as rs1466755713, COSV55712652; called by muse, mutect2, varscan2
- NCALD | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55271092, COSV55273830; called by muse, mutect2, varscan2
- NCOA5 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.88); PolyPhen benign (0.084); catalogued as COSV51642337; called by muse, mutect2, varscan2
- NF1 | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as CD076845, CM143334, COSV62193025; called by muse, mutect2, varscan2
- NF1 | c.4796C>T p.S1599F (on ENST00000358273 / NM_001042492.3; = p.S1578F on NM_000267.3) | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM077303, COSV62193034, COSV62193541, COSV62220082; called by muse, mutect2, varscan2
- NFASC | c.1474C>T p.R492C (on ENST00000339876 / NM_001378329.1; = p.R503C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/206 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs531423904, COSV100362363, COSV58358373; called by muse, mutect2, varscan2
- NFKB1 | c.2720C>T p.S907L (on ENST00000394820 / NM_001382627.1; = p.S908L on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs369577304; called by muse, varscan2
- NGF | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772557857, COSV101049373, COSV65686846; called by mutect2, varscan2
- NHS | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66271337; called by muse, mutect2, varscan2
- NID1 | c.424T>C p.F142L | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV51614918; called by muse, mutect2, varscan2
- NLRP11 | c.2828G>A p.S943N | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV64085594; called by muse, mutect2, varscan2
- NLRP11 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.379); catalogued as rs1265659363, COSV64085660; called by muse, mutect2, varscan2
- NLRP13 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/42 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as rs1459936417, COSV61619938; called by mutect2, varscan2
- NLRP14 | c.3088G>C p.G1030R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV100204739, COSV55064005; called by muse, mutect2, varscan2
- NLRP3 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 56/59 reads (95%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV60219978, COSV60230909; called by muse, mutect2, varscan2
- NLRP3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 142/148 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs180177470, CM068026, COSV60219989; ClinVar: not provided; called by muse, mutect2, varscan2
- NLRP4 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56707826, COSV56725773; called by muse, mutect2, varscan2
- NLRP9 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100243011, COSV60459540; called by muse, mutect2, varscan2
- NME8 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs151218163, COSV52253530; called by muse, varscan2
- NME9 | c.701G>A p.R234K (on ENST00000333911 / NM_001349024.2; = p.R173K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 226/524 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV58616614; called by muse, varscan2
- NOC2L | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs1349015128, COSV58530823; called by muse, mutect2, varscan2
- NOL4 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV52338537; called by muse, mutect2, varscan2
- NOP53 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV99884210; called by muse, mutect2, varscan2
- NOS1 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV57606672; called by muse, varscan2
- NOTCH4 | c.3622C>T p.P1208S | Missense Mutation (SNP) | VAF 187/307 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as COSV100900534; called by muse, mutect2, varscan2
- NPAP1 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.437); catalogued as COSV61504466; called by muse, mutect2, varscan2
- NPAS4 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs368915421; called by muse, mutect2, varscan2
- NPTX2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs141241960, COSV55716182; called by muse, mutect2, varscan2
- NRP1 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55158906, COSV55159847; called by muse, mutect2, varscan2
- NTN4 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.73); catalogued as rs369926222; called by muse, mutect2, varscan2
- NTNG2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.82); PolyPhen benign (0.078); catalogued as COSV62364407; called by muse, mutect2, varscan2
- NUP210 | c.4967A>C p.K1656T | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV54402300; called by muse, mutect2, varscan2
- NYAP2 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as COSV55998355; called by muse, mutect2, varscan2
- OAS3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.054); catalogued as COSV57444038; called by muse, mutect2, varscan2
- OBI1 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as COSV56144477; called by muse, varscan2
- OCLN | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as COSV62284839; called by muse, mutect2, varscan2
- OGDHL | c.2279A>T p.N760I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV65100760; called by muse, mutect2, varscan2
- OR10AG1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56631442; called by muse, mutect2, varscan2
- OR10G2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs751824895, COSV73390303; called by muse, mutect2, varscan2
- OR10G3 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57809630; called by muse, mutect2, varscan2
- OR10K2 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 105/110 reads (95%) | catalogued as COSV59220440, COSV59222447; called by muse, mutect2, varscan2
- OR1G1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100187520; called by muse, mutect2, varscan2
- OR1J1 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 61/66 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV52237207; called by muse, mutect2, varscan2
- OR1L3 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 91/104 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV59169116; called by muse, mutect2, varscan2
- OR2A2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 112/174 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs755445994, COSV68871044; called by muse, mutect2, varscan2
- OR2C1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV59239558; called by muse, mutect2, varscan2
- OR2C3 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV63574368; called by muse, varscan2
- OR2F2 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs767350080, COSV68832518; called by muse, mutect2, varscan2
- OR2H1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65810642; called by muse, mutect2, varscan2
- OR2H1 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs777238942, COSV101009803; called by muse, mutect2, varscan2
- OR2L3 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 330/339 reads (97%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs267598495, COSV63454411, COSV63454586; called by muse, mutect2, varscan2
- OR2Y1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57135964, COSV57136813; called by muse, mutect2, varscan2
- OR4K5 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV60002313; called by muse, mutect2, varscan2
- OR4N5 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV61320034; called by muse, mutect2, varscan2
- OR4Q3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177294; called by muse, mutect2, varscan2
- OR4Q3 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.839); catalogued as COSV59177302; called by muse, mutect2, varscan2
- OR51A2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100985020; called by muse, varscan2
- OR51F2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs773522707, COSV59063713, COSV59065439; called by muse, mutect2, varscan2
- OR51G1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775482982, COSV58968393; called by muse, mutect2, varscan2
- OR51I2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 79/169 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58297907, COSV58298809; called by muse, mutect2, varscan2
- OR51Q1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1309989985, COSV56177831; called by muse, varscan2
- OR52E6 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.694); catalogued as COSV61431296; called by muse, mutect2, varscan2
- OR52I2 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs750606405, COSV57044174; called by muse, mutect2
- OR52J3 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV66746351; called by muse, mutect2, varscan2
- OR52M1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs267602886, COSV64172059; called by mutect2, varscan2
- OR5B17 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868743937, COSV62159822; called by muse, mutect2, varscan2
- OR5B17 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV62159863; called by muse, mutect2, varscan2
- OR6F1 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57466763; called by muse, mutect2, varscan2
- OR7D4 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100432613, COSV58071162; called by muse, mutect2, varscan2
- OR8H1 | c.749T>A p.F250Y | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV57292997; called by muse, mutect2, varscan2
- OR8S1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763762535, COSV59599361; called by muse, mutect2, varscan2
- OSBPL6 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51910863; called by muse, mutect2, varscan2
- OTOF | c.4049G>A p.G1350E (on ENST00000272371 / NM_194248.3; = p.G583E on NM_004802.4) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV55495553; called by muse, mutect2, varscan2
- PACRGL | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV54841407; called by muse, mutect2, varscan2
- PAMR1 | c.1448G>A p.G483E (on ENST00000619888 / NM_001001991.3; = p.G500E on NM_015430.4) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as rs1334368117, COSV53509623; called by muse, mutect2, varscan2
- PANX1 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV57132699; called by muse, mutect2, varscan2
- PAPPA2 | c.3837T>A p.F1279L | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV62790719; called by muse, mutect2, varscan2
- PAQR5 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100575426; called by muse, mutect2, varscan2
- PCARE | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1253679295, COSV59053048; called by muse, mutect2, varscan2
- PCDH18 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.24); catalogued as COSV61266393; called by muse, mutect2, varscan2
- PCDHA2 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.363); catalogued as rs782395206, COSV65364596; called by muse, mutect2, varscan2
- PCDHA3 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.31); catalogued as COSV63538847; called by muse, mutect2, varscan2
- PCDHA7 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV65334796; called by muse, mutect2, varscan2
- PCDHA8 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV100970564; called by muse, mutect2, varscan2
- PCDHB10 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.03); catalogued as COSV53375368; called by muse, mutect2, varscan2
- PCDHB3 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV50564152; called by muse, mutect2, varscan2
- PCDHB5 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV50647173; called by muse, mutect2, varscan2
- PCDHB7 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs782283058, COSV50753965; called by muse, mutect2, varscan2
- PCDHB7 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.055); catalogued as rs267600426, COSV50753987; called by muse, mutect2, varscan2
- PCDHGA12 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs375524585, COSV52743147; called by muse, mutect2, varscan2
- PCDHGA6 | c.1190C>A p.S397* | Nonsense Mutation (SNP) | VAF 35/74 reads (47%) | catalogued as rs770340172, COSV53898522, COSV54012512; called by muse, mutect2, varscan2
- PCDHGA6 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as COSV53898537; called by muse, mutect2, varscan2
- PCSK5 | c.4249G>A p.E1417K | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV70447143; called by muse, mutect2, varscan2
- PCSK9 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 201/218 reads (92%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs267598660, COSV56160616; called by muse, mutect2, varscan2
- PDE1C | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs550592420, COSV58503459; called by muse, mutect2, varscan2
- PDE1C | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs770988547, COSV58503478; called by muse, mutect2, varscan2
- PDE8B | c.2170G>A p.V724I | Missense Mutation (SNP) | VAF 298/606 reads (49%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.931); catalogued as COSV53732196; called by muse, mutect2, varscan2
- PDGFC | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV56845171; called by muse, mutect2, varscan2
- PEAK1 | c.3650C>T p.S1217F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56930720; called by muse, mutect2, varscan2
- PGR | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs768769081, COSV54796114; called by muse, mutect2, varscan2
- PHC3 | c.791C>T p.P264L (on ENST00000494943 / NM_001308116.2; = p.P276L on NM_024947.4) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.421); catalogued as COSV71948275; called by muse, mutect2, varscan2
- PHF24 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54272999; called by muse, mutect2, varscan2
- PIGG | c.1396C>T p.P466S (on ENST00000453061 / NM_001127178.3; = p.P458S on NM_017733.4) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.962); catalogued as COSV56316111; called by muse, mutect2, varscan2
- PIGZ | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs368445115; called by muse, mutect2, varscan2
- PIK3C2G | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV56796981; called by muse, mutect2, varscan2
- PIK3CG | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV63245489; called by muse, mutect2, varscan2
1,092 further variants in this file (402 protein-altering or splice-affecting, 641 silent, 49 other) are not listed here.
